Gene-level copy-number profile of tumor specimen C3N-02672-02 from CPTAC case C3N-02672, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.4 years (22,056 days).
Specimen C3N-02672-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 524ee16a-e204-4f64-9cd9-2a945fd8c3b3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02672-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/e96b5cff-d1c9-4d70-9159-a206bb3cb729

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 2: 6,676; copy number 3: 121; copy number 4: 42,689; copy number 5: 95; copy number 6: 8,440; copy number 7: 1; copy number 9: 1; copy number 10: 1; copy number 11: 26; copy number 13: 89; copy number 14: 21; copy number 15: 30; copy number 16: 55; copy number 28: 16; copy number 36: 8; copy number 40: 4; copy number 41: 19; copy number 42: 30; copy number 47: 11; copy number 75: 4; copy number 76: 1; copy number 79: 4; copy number 82: 6; copy number 85: 2; copy number 87: 43; copy number 110: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–4): RN7SL5P.
- chr15:24,162,754–24,240,192, 3 genes: PWRN2, AC087463.1, AC087463.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 372 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:66,638,667–67,302,485, 21 genes, copy number 14 (within-gene range 5–14): RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860, RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D.
- chr11:67,428,460–71,252,577, 120 genes, copy number 11–82 (broad region; genes not listed).
- chr11:77,659,996–83,423,516, 85 genes, copy number 42–110 (broad region; genes not listed).
- chr11:100,641,975–103,479,863, 60 genes, copy number 15–47: RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr11:118,193,725–119,190,223, 68 genes, copy number 13 (within-gene range 4–13) (broad region; genes not listed).
- chr16:32,475,051–32,788,944, 17 genes, copy number 10–11: ABCD1P3, AC137800.1, AC137800.2, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr20:52,890,162–52,890,386, 1 gene, copy number 9: RPL36P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
